Somatic mutation profile of tumor specimen ALCH-B1Y2-TTP1-A (aliquot ALCH-B1Y2-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1Y2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.8 years (18,908 days).
Specimen ALCH-B1Y2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38914028-44d3-4a94-a93f-d45a8092b17b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1Y2-NB1-A (Blood Derived Normal), aliquot ALCH-B1Y2-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8f9560a-5b63-4a66-984f-779e0d550562

The open-access MAF lists 888 somatic variants for this specimen: 595 protein-altering or splice-affecting, 183 silent, 110 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 516, Silent 183, Intron 45, Nonsense Mutation 35, 5'UTR 23, 3'UTR 16, Splice Region 14, RNA 13, Frame Shift Del 10, Splice Site 10, 5'Flank 8, Frame Shift Ins 6.

Variants (750 of 888; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 451/1468 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.1115C>A p.T372K | Missense Mutation (SNP) | VAF 88/576 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863225235, CM090677; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 78/280 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; called by muse, mutect2, varscan2
- A1CF | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539075515; called by muse, mutect2
- ACTL8 | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV64862248; called by muse, mutect2
- ADGRG4 | c.3007C>G p.H1003D | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV54948523; called by muse, mutect2
- ADGRL3 | c.2732A>T p.N911I (on ENST00000506720 / NM_001322402.2; = p.N843I on NM_015236.6) | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547411; called by muse, mutect2, varscan2
- ADGRL4 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769722549, COSV66061014, COSV66061808; called by muse, mutect2, varscan2
- ADGRV1 | c.13499A>C p.H4500P | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV67985203, COSV67987556, COSV67995159; called by muse, mutect2, varscan2
- ALPG | c.767G>T p.W256L | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54968552; called by muse, mutect2, varscan2
- AMY2A | c.516C>T p.V172= | Splice Region (SNP) | VAF 38/711 reads (5%) | catalogued as COSV101340626; called by muse, mutect2
- APOB | c.6131A>G p.D2044G | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as rs1558564449; called by muse, mutect2, varscan2
- APOBEC3H | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV62379051; called by muse, mutect2, varscan2
- ARHGAP31 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs752955355, COSV51795950; called by muse, mutect2, varscan2
- ARHGAP35 | c.2749G>T p.G917* | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as COSV68335933; called by muse, mutect2, varscan2
- ASB3 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 173/847 reads (20%) | catalogued as rs1310934894, COSV99712578; called by muse, mutect2, varscan2
- ASH2L | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 38/508 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99166980; called by muse, mutect2
- ASTN2 | c.3781A>G p.R1261G (on ENST00000313400 / NM_001365069.1; = p.R1210G on NM_014010.5) | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV55998438; called by muse, mutect2
- ATP2C2 | c.1930-8G>T | Splice Region (SNP) | VAF 33/251 reads (13%) | catalogued as COSV52299753; called by muse, mutect2, varscan2
- ATP6V0A4 | c.417G>A p.E139= | Splice Region (SNP) | VAF 64/526 reads (12%) | catalogued as rs941957888; called by muse, mutect2, varscan2
- ATP8B3 | c.2975G>A p.R992Q | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs377095403; called by muse, mutect2, varscan2
- BACH2 | c.2237C>G p.P746R | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV57591226; called by muse, mutect2, varscan2
- BMP10 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 46/564 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750438622, COSV54896352; called by muse, mutect2
- BTN2A1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 54/473 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as rs779413549; called by muse, mutect2, varscan2
- C9orf131 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.346); catalogued as COSV100398272; called by muse, mutect2
- CCT8L2 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 132/436 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs372231331; called by muse, mutect2, varscan2
- CDH9 | c.2279G>C p.C760S | Missense Mutation (SNP) | VAF 59/348 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50251711, COSV50279379; called by muse, mutect2, varscan2
- CFAP61 | c.3108G>C p.K1036N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV99846045; called by muse, mutect2, varscan2
- CLCN1 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 38/992 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM076096; called by muse, mutect2
- CLSTN3 | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99867876; called by muse, mutect2
- CNTNAP4 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 25/489 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV100270627; called by muse, mutect2
- CNTNAP4 | c.1733C>A p.T578N | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56704838; called by muse, mutect2
- COL11A1 | c.2926G>C p.G976R | Missense Mutation (SNP) | VAF 60/507 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62186161; called by muse, mutect2, varscan2
- COL11A2 | c.3076G>A p.G1026R (on ENST00000341947 / NM_080680.3; = p.G919R on NM_080679.2) | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100553392; called by muse, mutect2, varscan2
- COL6A5 | c.4950G>A p.Q1650= | Splice Region (SNP) | VAF 42/462 reads (9%) | catalogued as rs1415935017; called by muse, mutect2
- COL6A5 | c.4950+1G>A p.X1650_splice | Splice Site (SNP) | VAF 40/455 reads (9%) | catalogued as rs1475220617; called by muse, mutect2
- CRYGC | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as CX162352; called by muse, mutect2, varscan2
- CST4 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 82/375 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV99463147; called by muse, mutect2, varscan2
- CTAG2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV55994250; called by muse, mutect2, varscan2
- CTNNA3 | c.1568T>C p.I523T | Missense Mutation (SNP) | VAF 76/790 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.803); catalogued as rs762067610; called by muse, mutect2
- CTRC | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 17/491 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1428850483, COSV101036274, COSV65621435; called by muse, mutect2
- CYP11B2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100010930; called by muse, mutect2
- DCAF4L1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as rs143365042; called by muse, mutect2, varscan2
- DCAF4L2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs755701425, COSV60476952, COSV60481637; called by muse, mutect2, varscan2
- DGKI | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs758676334; called by muse, mutect2, varscan2
- DNAH9 | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as rs780008412; called by muse, mutect2
- DNAI2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755060592, COSV56757062; called by muse, mutect2
- DOCK2 | c.4381-3C>G | Splice Region (SNP) | VAF 119/408 reads (29%) | catalogued as COSV99912028, COSV99914282; called by muse, mutect2, varscan2
- DOCK8 | c.5701C>G p.L1901V | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs1454023317; called by muse, mutect2, varscan2
- DPY19L2 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60542442; called by muse, mutect2
- EEF2K | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV53783370; called by muse, mutect2
- EPG5 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as rs201678945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA8 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV51295893; called by muse, mutect2
- ERBB4 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 36/854 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV53501755; called by muse, mutect2
- ERCC3 | c.2255G>T p.G752V | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53427317; called by muse, mutect2, varscan2
- F13B | c.1069G>T p.G357W | Missense Mutation (SNP) | VAF 64/502 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66374765; called by muse, mutect2, varscan2
- FAM78B | c.286T>G p.L96V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57983122; called by muse, mutect2, varscan2
- FAM83H | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV66353653; called by muse, mutect2, varscan2
- FAM9A | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.302); catalogued as COSV66813384, COSV66813678; called by muse, mutect2, varscan2
- FBXO2 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372591058; called by muse, mutect2, varscan2
- FFAR4 | c.568-1G>A p.X190_splice | Splice Site (SNP) | VAF 36/169 reads (21%) | catalogued as COSV65178845, COSV65178950; called by muse, mutect2, varscan2
- FGF5 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV56892905; called by muse, mutect2, varscan2
- FKBP1C | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as rs530406188; called by muse, mutect2, varscan2
- FMN2 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.648); catalogued as rs1265543967, COSV60459463; called by muse, mutect2, varscan2
- FOLR3 | c.112A>G p.M38V | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs1006933536; called by muse, mutect2
- FOXE1 | c.1069C>A p.R357S | Missense Mutation (SNP) | VAF 119/438 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765994883; called by muse, mutect2, varscan2
- FRG2C | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 66/727 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57311821; called by muse, mutect2
- FSD2 | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 116/370 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1295471615; called by muse, mutect2, varscan2
- FSHR | c.1206C>A p.C402* | Nonsense Mutation (SNP) | VAF 168/777 reads (22%) | catalogued as COSV100436518; called by muse, mutect2, varscan2
- FSIP2 | c.15490G>C p.E5164Q | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV58080738; called by muse, mutect2
- FSTL5 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 72/424 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV60207095; called by muse, mutect2, varscan2
- GJA10 | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV65355093; called by muse, mutect2, varscan2
- GUCY1A1 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773825636, COSV99638821; called by muse, mutect2
- HLA-A | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100954195; called by muse, varscan2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2, varscan2
- IGHV3-23 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 78/577 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as rs368753240; called by muse, mutect2, varscan2
- IL25 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs963519298, COSV100198035; called by muse, mutect2, varscan2
- IRS4 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 164/325 reads (50%) | catalogued as COSV64533177; called by muse, mutect2, varscan2
- ISM1 | c.895C>A p.R299S | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52603046; called by muse, mutect2
- JUP | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.028); catalogued as rs1555606954; called by muse, mutect2, varscan2
- KANSL3 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100831257; called by muse, mutect2, varscan2
- KARS1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs767363060; called by muse, mutect2, varscan2
- KCNB1 | c.2081C>A p.P694H | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen possibly damaging (0.772); catalogued as COSV65569989; called by muse, mutect2, varscan2
- KCNB2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 15/289 reads (5%) | catalogued as COSV99074162; called by muse, mutect2
- KCTD8 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 91/446 reads (20%) | catalogued as COSV63587770; called by muse, mutect2, varscan2
- KDM5C | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as COSV64772222; called by muse, mutect2, varscan2
- KIAA1671 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 29/377 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs964201773; called by muse, mutect2
- KIF2B | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV52133506; called by muse, mutect2, varscan2
- KIRREL1 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1558015507; called by muse, mutect2, varscan2
- LAMA1 | c.1257C>A p.H419Q | Missense Mutation (SNP) | VAF 35/416 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67535183; called by muse, mutect2
- LCE2B | c.226C>A p.H76N | Missense Mutation (SNP) | VAF 52/453 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.969); catalogued as COSV64227722; called by muse, mutect2, varscan2
- LPIN1 | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 60/543 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56769009; called by muse, mutect2, varscan2
- LRP1B | c.6162G>T p.L2054F | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV67245067; called by muse, mutect2, varscan2
- LRP1B | c.1675C>A p.R559S | Missense Mutation (SNP) | VAF 53/515 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV67196367; called by muse, mutect2, varscan2
- LRP2 | c.1834G>T p.G612C | Missense Mutation (SNP) | VAF 102/676 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99787777; called by muse, mutect2, varscan2
- LSM14A | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 13/440 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV70885285; called by muse, mutect2
- MAGEB16 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778116835; called by muse, mutect2
- MAGI1 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 19/566 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1306679602; called by muse, mutect2
- MATN4 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | PolyPhen probably damaging (0.997); catalogued as COSV100636981; called by muse, mutect2, varscan2
- MMP16 | c.1780C>A p.R594S | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749473846, COSV54156260, COSV99685589; called by muse, mutect2
- MPO | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 116/454 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs774618810; called by muse, mutect2, varscan2
- MUC16 | c.19703G>A p.S6568N | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as rs772888879; called by muse, mutect2, varscan2
- MYH1 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 90/353 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56848097; called by muse, mutect2, varscan2
- MYH7 | c.1260G>A p.V420= | Splice Region (SNP) | VAF 39/618 reads (6%) | catalogued as rs1555338342; ClinVar: likely benign; called by muse, mutect2
- MYO3A | c.1077G>C p.E359D | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV56352888; called by muse, mutect2
- NAGLU | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as rs1476229395; called by muse, mutect2, varscan2
- NDST4 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52118317; called by muse, mutect2, varscan2
- NF1 | c.4724+1G>T p.X1575_splice (on ENST00000358273 / NM_001042492.3; = p.X1554_splice on NM_000267.3) | Splice Site (SNP) | VAF 54/317 reads (17%) | catalogued as CS093231, COSV62200302, COSV62209406; called by muse, mutect2, varscan2
- NLRP11 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs756242927; called by muse, mutect2, varscan2
- NOBOX | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1203231695; called by muse, mutect2, varscan2
- NPAS3 | c.1866C>A p.S622R (on ENST00000356141 / NM_001164749.2; = p.S590R on NM_022123.3) | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.634); catalogued as rs1219176217; called by muse, mutect2, varscan2
- NRCAM | c.2112G>T p.Q704H (on ENST00000379028 / NM_001371124.1; = p.Q688H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/651 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV61035032; called by muse, mutect2, varscan2
- NTNG1 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 60/584 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53971495; called by muse, mutect2, varscan2
- NTRK1 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62328314; called by muse, mutect2, varscan2
- OGDHL | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934482; called by muse, mutect2, varscan2
- OR10P1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs772594253, COSV59007644; called by muse, mutect2, varscan2
- OR11H1 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV99421850; called by mutect2, varscan2
- OR11H2 | c.267C>A p.F89L (on ENST00000556246; = p.F100L on NM_001197287.1) | Missense Mutation (SNP) | VAF 45/541 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs1380551343; called by muse, mutect2, varscan2
- OR13A1 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV65572709; called by muse, mutect2
- OR13C4 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143999819, COSV99469873; called by muse, mutect2, varscan2
- OR13C5 | c.764T>A p.I255N | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1344672640; called by muse, mutect2, varscan2
- OR1F1 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 101/448 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764702382, COSV58962856; called by muse, mutect2, varscan2
- OR4C16 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58942002; called by muse, mutect2, varscan2
- OR52I2 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57045868; called by muse, mutect2, varscan2
- OR5F1 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148461158; called by muse, mutect2
- OR5T1 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV57303928; called by muse, mutect2
- OR5T3 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV57383117; called by muse, mutect2
- P3H2 | c.2026A>G p.R676G | Missense Mutation (SNP) | VAF 173/533 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.416); catalogued as COSV100078402; called by muse, mutect2, varscan2
- P3H2 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs878885298; called by muse, mutect2, varscan2
- PABPC3 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV55797970; called by muse, varscan2
- PALLD | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV54973238; called by muse, mutect2, varscan2
- PCDH15 | c.5266C>A p.P1756T | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100227106; called by muse, mutect2, varscan2
- PCDH9 | c.3714A>C p.*1238Yext*26 (on ENST00000377865 / NM_203487.3; = p.*1204Yext*26 on NM_020403.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV60531117, COSV60535317, COSV60559707; called by muse, mutect2, varscan2
- PCDHA12 | c.1873G>C p.G625R | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99165013; called by muse, mutect2, varscan2
- PCDHGB2 | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs748119164; called by muse, mutect2, varscan2
- PCK1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 187/500 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368269624; called by muse, mutect2, varscan2
- PDE3A | c.2815C>A p.L939I | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62976252; called by muse, varscan2
- PDZD2 | c.1865A>G p.N622S | Missense Mutation (SNP) | VAF 90/473 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1022822927; called by muse, mutect2, varscan2
- PDZRN3 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55197166, COSV55216163; called by muse, mutect2, varscan2
- PITPNM1 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201076041; called by muse, mutect2, varscan2
- PJVK | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57867725, COSV57869813; called by muse, mutect2, varscan2
- PLCXD3 | c.627del p.Q210Rfs*2 | Frame Shift Del (DEL) | VAF 113/401 reads (28%) | catalogued as rs1165324286, COSV100125429; called by mutect2, pindel, varscan2
- PLXND1 | c.4718G>T p.R1573L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100139950; called by muse, mutect2, varscan2
- POLD1 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV70955328; called by muse, mutect2, varscan2
- POPDC2 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV99950937; called by muse, mutect2, varscan2
- PTPRK | c.3230C>A p.P1077H (on ENST00000368215 / NM_001291984.2; = p.P1078H on NM_002844.4) | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63893685; called by muse, mutect2
- PXDNL | c.1717C>A p.P573T | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100685053, COSV62492793; called by muse, mutect2
- PYROXD1 | c.729G>C p.L243F | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as rs1205911414; called by muse, mutect2
- RASGRF1 | c.802C>A p.R268S | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV69177458; called by muse, mutect2, varscan2
- RBP3 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 62/601 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as rs199801954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIC1 | c.1349C>G p.S450C | Missense Mutation (SNP) | VAF 204/669 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs768734697; called by muse, mutect2, varscan2
- ROR2 | c.2701C>A p.P901T | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV100996156; called by muse, mutect2, varscan2
- RYR1 | c.3556G>T p.G1186C | Missense Mutation (SNP) | VAF 110/339 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62089929; called by muse, mutect2, varscan2
- RYR2 | c.5002G>T p.G1668W | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100773432; called by muse, mutect2, varscan2
- SAMM50 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768642813; called by muse, mutect2, varscan2
- SCN11A | c.826A>T p.M276L | Missense Mutation (SNP) | VAF 112/355 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs755454113; called by muse, mutect2, varscan2
- SCUBE1 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV51814853; called by muse, mutect2, varscan2
- SDK2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs769049365; called by muse, mutect2
- SERPINB13 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs534246315, COSV54027942; called by muse, mutect2, varscan2
- SFRP2 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.158); catalogued as COSV56838189; called by muse, mutect2
- SH3BP2 | c.1598G>A p.S533N | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs1435214571; called by muse, mutect2
- SH3RF1 | c.2458G>A p.G820S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1194848504; called by muse, mutect2
- SIGLEC11 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs748087006; called by muse, mutect2
- SLC22A1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.327); catalogued as COSV61451703; called by muse, mutect2, varscan2
- SLCO4A1 | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 119/365 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs756481285; called by muse, mutect2, varscan2
- SLIT1 | c.2134G>T p.V712L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV99821536; called by muse, varscan2
- SLIT2 | c.3902G>T p.G1301V | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.279); catalogued as COSV99881029; called by muse, mutect2
- SLITRK4 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV62025202; called by muse, mutect2, varscan2
- SLITRK4 | c.291C>A p.N97K | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV100567376; called by muse, mutect2, varscan2
- SMIM20 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV101541823; called by muse, mutect2, varscan2
- SNX30 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1473306263; called by mutect2, varscan2
- SPAG17 | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100308170, COSV60468876; called by muse, mutect2, varscan2
- SPTLC3 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65465188; called by muse, mutect2
- SRRM4 | c.526C>G p.R176G | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs777284178, COSV57413547; called by muse, mutect2, varscan2
- ST8SIA3 | c.562C>A p.R188S | Missense Mutation (SNP) | VAF 34/188 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV60653938; called by muse, mutect2, varscan2
- SULT6B1 | c.418C>T p.R140* (on ENST00000535679 / NM_001367551.1; = p.R102* on NM_001032377.2) | Nonsense Mutation (SNP) | VAF 40/290 reads (14%) | catalogued as rs147099571, COSV53194210; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2221G>T p.A741S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs1181975174; called by muse, mutect2, varscan2
- SYCP2 | c.2354A>G p.Q785R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62766959; called by mutect2, varscan2
- SYNE3 | c.1539G>T p.E513D | Missense Mutation (SNP) | VAF 47/545 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV62080574; called by muse, mutect2
- TBX18 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.798); catalogued as COSV100858375; called by muse, mutect2, varscan2
- TDRD15 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1035656558; called by muse, mutect2
- TEX13C | c.2405C>A p.P802H | Missense Mutation (SNP) | VAF 132/230 reads (57%) | SIFT tolerated (0.29); catalogued as rs1201640594; called by muse, varscan2
- TFAP2B | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs1422801256; called by muse, mutect2, varscan2
- TLL1 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 44/558 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV50278891; called by muse, mutect2
- TMEM216 | c.349G>C p.E117Q (on ENST00000515837 / NM_001173990.3; = p.E56Q on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/543 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1278856461; called by muse, mutect2, varscan2
- TMEM247 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.998); catalogued as rs768940112; called by muse, varscan2
- TMPRSS11B | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 63/546 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.131); catalogued as COSV60291923; called by muse, mutect2, varscan2
- TOP2A | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.735); catalogued as rs781108895; called by muse, mutect2, varscan2
- TRANK1 | c.3964G>T p.G1322W | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57151780; called by muse, mutect2, varscan2
- TRAV7 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 55/452 reads (12%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.986); catalogued as rs1342369948; called by muse, mutect2, varscan2
- TRIM10 | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.185); catalogued as rs543330371; called by muse, mutect2, varscan2
- TRIM15 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as rs750050344; called by muse, mutect2, varscan2
- TRIM3 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.329); catalogued as rs373524727, COSV61985078, COSV61985885; called by muse, mutect2
- TRIM64C | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 26/880 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.522); catalogued as rs1344104319; called by muse, mutect2
- TRPA1 | c.2877G>C p.L959F | Missense Mutation (SNP) | VAF 74/791 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51557679; called by muse, mutect2
- TSPYL4 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1442525396; called by muse, mutect2
- TTN | c.8764G>T p.E2922* (on ENST00000591111; = p.E2876* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 51/430 reads (12%) | catalogued as COSV60326897; called by muse, mutect2, varscan2
- USP43 | c.2837G>T p.R946L | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV53301758; called by muse, mutect2, varscan2
- VCPIP1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60046231; called by muse, mutect2, varscan2
- VSIG4 | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV99058261; called by muse, mutect2
- XIRP1 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371304146; called by muse, varscan2
- ZNF454 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 25/209 reads (12%) | catalogued as COSV60769104; called by muse, mutect2, varscan2
- ZNF804A | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV56447926; called by muse, mutect2, varscan2
- ZP4 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 109/412 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100850609, COSV63910850; called by muse, mutect2, varscan2
- AATK | c.51C>A p.D17E | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ABCA6 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2
- ABCC12 | c.3383G>A p.R1128K | Missense Mutation (SNP) | VAF 87/381 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ACTN1 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- ACTN2 | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- ADAM19 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 146/490 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAM29 | c.1652G>T p.C551F | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM33 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY10 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 135/465 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADCY8 | c.2291A>T p.Y764F | Missense Mutation (SNP) | VAF 32/646 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- ADGRD2 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ADGRL2 | c.4118C>T p.T1373I (on ENST00000370717 / NM_001366005.1; = p.T1317I on NM_012302.4) | Missense Mutation (SNP) | VAF 95/386 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADGRL3 | c.2008C>G p.L670V (on ENST00000506720 / NM_001322402.2; = p.L602V on NM_015236.6) | Missense Mutation (SNP) | VAF 60/639 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); called by muse, mutect2
- ADGRL3 | c.2959A>G p.S987G (on ENST00000506720 / NM_001322402.2; = p.S919G on NM_015236.6) | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ADI1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- AEBP2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHCTF1 | c.5243C>G p.S1748C (on ENST00000366508; = p.S1722C on NM_015446.5) | Missense Mutation (SNP) | VAF 97/454 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- AHNAK2 | c.4252A>T p.S1418C | Missense Mutation (SNP) | VAF 22/562 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- AK9 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AMBRA1 | c.1927_1929del p.E643del (on ENST00000458649 / NM_001367468.1; = p.E553del on NM_017749.3 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 26/239 reads (11%) | called by pindel, varscan2
- ANK2 | c.6238G>A p.A2080T | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD30B | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 102/751 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- ANKRD33B | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2
- ANO2 | c.79C>G p.P27A (on ENST00000356134 / NM_001278597.3; = p.P31A on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOA4 | c.557T>A p.L186H | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- APOLD1 | c.121G>A p.E41K (on ENST00000326765 / NM_001130415.2; = p.E10K on NM_030817.3) | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- APP | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.478); called by muse, mutect2
- APPBP2 | c.1059A>T p.A353= | Splice Region (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.350C>A p.A117D (on ENST00000409202 / NM_001007231.3; = p.A110D on NM_014882.3) | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ARHGEF10L | c.2875G>T p.D959Y | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ARL14 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 47/486 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2
- ARMC4 | c.2389G>T p.G797C | Missense Mutation (SNP) | VAF 221/932 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP11B | c.3208G>A p.G1070S | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ATP8B3 | c.3202G>T p.G1068W | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATR | c.7108C>G p.L2370V | Missense Mutation (SNP) | VAF 70/288 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN7L1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- BBS10 | c.2071G>T p.V691F | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCAT1 | c.1053C>A p.H351Q | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.147); called by muse, mutect2
- BICD1 | c.2893C>G p.P965A | Missense Mutation (SNP) | VAF 74/755 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- BIRC6 | c.7358C>T p.S2453L | Missense Mutation (SNP) | VAF 46/672 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2
- BTRC | c.326C>G p.T109R (on ENST00000370187 / NM_033637.4; = p.T73R on NM_003939.5) | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.009); called by muse, mutect2
- C20orf194 | c.3487G>T p.E1163* | Nonsense Mutation (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2, varscan2
- C4orf54 | c.4166C>A p.P1389Q | Missense Mutation (SNP) | VAF 55/312 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C6orf118 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- C9orf24 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA2D1 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 103/451 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA2D4 | c.2996-3C>A | Splice Region (SNP) | VAF 81/375 reads (22%) | called by muse, mutect2, varscan2
- CACTIN | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 27/187 reads (14%) | called by muse, mutect2, varscan2
- CARS1 | c.1608G>T p.R536S | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC148 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2
- CCDC168 | c.3478G>C p.E1160Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); called by mutect2, varscan2
- CCDC74A | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 62/614 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2
- CD1E | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP290 | c.1503G>T p.E501D | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CFAP46 | c.3497C>G p.S1166W | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CFAP54 | c.6015A>T p.Q2005H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CFHR1 | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 77/774 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.07); called by muse, mutect2
- CGNL1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHL1 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CHRNA2 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- CLEC18B | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 60/744 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2
- CLEC2A | c.502A>C p.S168R | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, varscan2
- CLEC6A | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLRN2 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- CNKSR1 | c.779G>T p.G260V (on ENST00000374253 / NM_001297647.2; = p.G253V on NM_006314.3) | Missense Mutation (SNP) | VAF 132/466 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CNTLN | c.3883G>T p.V1295F | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CNTN5 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CNTNAP4 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COL15A1 | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL16A1 | c.1621G>T p.G541* | Nonsense Mutation (SNP) | VAF 33/282 reads (12%) | called by muse, mutect2, varscan2
- COL6A5 | c.5515G>T p.E1839* (on ENST00000312481; = p.E1835* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/676 reads (3%) | called by muse, mutect2
- COMP | c.1603C>G p.Q535E | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- COPG1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- COQ4 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CORIN | c.2791T>A p.W931R | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CPED1 | c.3016C>T p.P1006S | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CREB3L2 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CRHBP | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CRNN | c.64del p.E22Rfs*12 | Frame Shift Del (DEL) | VAF 32/224 reads (14%) | called by mutect2, pindel, varscan2
- CRTAM | c.193+1G>A p.X65_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- CSMD2 | c.4648T>C p.Y1550H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- CTNNA3 | c.1365G>T p.L455F | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CYP11B1 | c.1439A>T p.D480V | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP4F22 | c.939G>T p.R313S | Missense Mutation (SNP) | VAF 117/416 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCAF1 | c.2506G>T p.D836Y | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- DCAF4L2 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 20/551 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- DCN | c.330G>T p.L110F | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDR2 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 72/685 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- DDX46 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.079); called by muse, mutect2
- DMD | c.4894A>G p.T1632A | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DMKN | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAI3 | c.1447A>T p.T483S | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); called by muse, mutect2
- DNAJC1 | c.1448A>G p.E483G | Missense Mutation (SNP) | VAF 30/689 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2
- DPY19L2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DRD5 | c.1038G>T p.W346C | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DYTN | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2
- EFCC1 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EGLN1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); called by muse, mutect2
- EIF3F | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- EML5 | c.3278-2A>C p.X1093_splice | Splice Site (SNP) | VAF 59/249 reads (24%) | called by muse, mutect2, varscan2
- EP300 | c.5427C>G p.I1809M | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- EPG5 | c.2800A>T p.K934* | Nonsense Mutation (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
- EPHA7 | c.780dup p.G261Wfs*17 | Frame Shift Ins (INS) | VAF 39/232 reads (17%) | called by mutect2, pindel, varscan2
- EPS8L3 | c.1599G>T p.E533D (on ENST00000361965 / NM_133181.4; = p.E503D on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ERGIC1 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- EVC | c.2235del p.Q746Rfs*26 | Frame Shift Del (DEL) | VAF 36/256 reads (14%) | called by mutect2, pindel, varscan2
- EYS | c.5336G>A p.G1779D | Missense Mutation (SNP) | VAF 21/411 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- F11 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 88/510 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- F13A1 | c.-20A>G | Splice Region (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- F2RL2 | c.208T>C p.C70R | Missense Mutation (SNP) | VAF 146/480 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- FAM160A1 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 106/575 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM161A | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 119/438 reads (27%) | called by muse, mutect2, varscan2
- FAM193B | c.2404C>A p.Q802K | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- FAM205A | c.1611del p.W537Cfs*64 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, varscan2
- FAM47C | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 115/263 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- FANCB | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- FAT3 | c.7120C>A p.L2374M | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FBXO8 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 119/515 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FBXW5 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2
- FCN2 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 30/467 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); called by muse, mutect2
- FER1L6 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 23/521 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.019); called by muse, mutect2
- FEZ1 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FHL1 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FRAS1 | c.1072-2A>G p.X358_splice | Splice Site (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- FRG2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 56/748 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- FRMPD2 | c.2247dup p.V750Cfs*11 | Frame Shift Ins (INS) | VAF 54/251 reads (22%) | called by mutect2, pindel, varscan2
- FSIP2 | c.6685C>A p.Q2229K | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- FSTL5 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 71/801 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- G2E3 | c.1500G>T p.R500S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- GARS1 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 46/777 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GKAP1 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- GLP2R | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GLYAT | c.570T>A p.N190K | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GNAZ | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- GOLGA7B | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- GOLGA8F | c.341C>A p.A114E (on ENST00000526619; = p.A320E on NM_001350920.2) | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.981); called by muse, varscan2
- GOLGA8T | c.1867T>A p.W623R | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- GPAT4 | c.1013G>C p.S338T | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- GPATCH8 | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 26/528 reads (5%) | called by muse, mutect2
- GPR137C | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- GPR158 | c.3107T>A p.M1036K | Missense Mutation (SNP) | VAF 14/546 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2
- GPRC5B | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- GRAP2 | c.168C>T p.P56= | Splice Region (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- GRHL1 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.04); called by mutect2, varscan2
- GRIP2 | c.1681C>A p.L561I (on ENST00000619221; = p.L464I on NM_001080423.4) | Missense Mutation (SNP) | VAF 94/267 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- GRM1 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GSTA2 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 54/556 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HACE1 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- HCN4 | c.2756C>A p.S919Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- HCN4 | c.2093T>A p.M698K | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2
- HEPACAM2 | c.1309G>T p.V437L (on ENST00000394468 / NM_001039372.4; = p.V425L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/528 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HEPACAM2 | c.1202G>T p.G401V (on ENST00000394468 / NM_001039372.4; = p.G389V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPH | c.760T>A p.S254T (on ENST00000343002; = p.S308T on NM_138737.5) | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- HIVEP3 | c.4762G>T p.D1588Y | Missense Mutation (SNP) | VAF 83/401 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- HMCN1 | c.16898A>G p.Y5633C | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- HOXA5 | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, varscan2
- HOXA5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, varscan2
- HR | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- HYAL3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.037); called by muse, mutect2
- IGHV1OR15-9 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- IGKV1D-16 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 89/612 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- IGKV1D-17 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 95/1027 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- INHBE | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INPP4B | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- INPP5B | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA8 | c.2667G>T p.E889D | Missense Mutation (SNP) | VAF 105/391 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ITGAE | c.3514G>T p.E1172* | Nonsense Mutation (SNP) | VAF 23/249 reads (9%) | called by muse, mutect2
- IWS1 | c.2328G>T p.R776S | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- JMJD1C | c.6412G>A p.E2138K | Missense Mutation (SNP) | VAF 23/401 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2
- KANK4 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KATNAL2 | c.687G>T p.M229I (on ENST00000356157 / NM_001353899.1; = p.M157I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNC1 | c.1137T>A p.S379R | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KCNE4 | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- KCNJ16 | c.258G>T p.L86F | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNU1 | c.1189dup p.W397Lfs*25 | Frame Shift Ins (INS) | VAF 43/421 reads (10%) | called by pindel, varscan2
- KIAA1614 | c.3420del p.G1142Afs*61 | Frame Shift Del (DEL) | VAF 16/145 reads (11%) | called by mutect2, pindel, varscan2
- KIAA2012 | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KIRREL1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2
- KLHL29 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- KLHL3 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL32 | c.926A>T p.Y309F | Missense Mutation (SNP) | VAF 73/571 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLRD1 | c.164-1G>T p.X55_splice | Splice Site (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2
- KRT81 | c.1196T>A p.L399Q | Missense Mutation (SNP) | VAF 58/476 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP10-1 | c.437del p.C146Sfs*182 | Frame Shift Del (DEL) | VAF 61/370 reads (16%) | called by mutect2, pindel, varscan2
- L3MBTL3 | c.2164G>T p.G722W | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMB4 | c.4092G>C p.K1364N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2
- LMLN | c.917C>G p.P306R | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.213); called by muse, mutect2
- LOXL3 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRCH3 | c.1198A>C p.S400R | Missense Mutation (SNP) | VAF 56/604 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2
- LRP1B | c.12527G>T p.C4176F | Missense Mutation (SNP) | VAF 57/551 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LRP1B | c.9033A>T p.S3011= | Splice Region (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- LRRC14B | c.1161C>A p.C387* | Nonsense Mutation (SNP) | VAF 48/267 reads (18%) | called by muse, mutect2, varscan2
- LYST | c.3198G>C p.E1066D | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAGEL2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAGI3 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 65/499 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARCHF4 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MBNL3 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MBNL3 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCCC1 | c.95G>C p.W32S | Missense Mutation (SNP) | VAF 38/639 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- MCM3 | c.2038G>C p.D680H (on ENST00000229854 / NM_001366374.2; = p.D670H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/509 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- MDGA2 | c.955G>T p.D319Y (on ENST00000399232 / NM_001113498.2; = p.D21Y on NM_182830.4) | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MED13 | c.3184G>T p.V1062F | Missense Mutation (SNP) | VAF 42/489 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- MFN2 | c.1635C>G p.F545L | Missense Mutation (SNP) | VAF 21/633 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGA | c.5728C>T p.Q1910* (on ENST00000219905 / NM_001164273.1; = p.Q1701* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 95/294 reads (32%) | called by muse, mutect2, varscan2
- MGAM2 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.436); called by muse, mutect2
- MICALL2 | c.2045del p.P682Rfs*43 | Frame Shift Del (DEL) | VAF 45/225 reads (20%) | called by mutect2, pindel, varscan2
- MMRN1 | c.3114T>G p.Y1038* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | called by muse, varscan2
- MROH5 | c.2641A>G p.M881V | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- MT1B | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTIF2 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 62/766 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- MUC16 | c.21746G>T p.R7249M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MUC16 | c.6682G>T p.G2228C | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC19 | n.23799C>T | Splice Region (SNP) | VAF 13/215 reads (6%) | called by muse, mutect2
- MYLK2 | c.1508A>T p.E503V | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2
- MYO1F | c.2344T>A p.L782M | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- MYOM2 | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOM3 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- NBEA | c.4717G>C p.V1573L | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NCAPH | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFC2 | c.222dup p.V75Cfs*4 | Frame Shift Ins (INS) | VAF 121/411 reads (29%) | called by mutect2, pindel, varscan2
- NECAP1 | c.302-3C>T | Splice Region (SNP) | VAF 66/515 reads (13%) | called by mutect2, varscan2
- NF1 | c.4724G>T p.R1575M (on ENST00000358273 / NM_001042492.3; = p.R1554M on NM_000267.3) | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NF1 | c.5042A>T p.N1681I (on ENST00000358273 / NM_001042492.3; = p.N1660I on NM_000267.3) | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFKBIZ | c.2140A>T p.R714* | Nonsense Mutation (SNP) | VAF 32/520 reads (6%) | called by muse, mutect2
- NOL12 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NOX4 | c.257C>G p.S86* | Nonsense Mutation (SNP) | VAF 39/253 reads (15%) | called by muse, mutect2, varscan2
- NPHP1 | c.1895G>T p.G632V (on ENST00000393272 / NM_207181.4; = p.G633V on NM_000272.5) | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- NTRK1 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OPCML | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.212); called by mutect2, varscan2
- OR10A4 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- OR2AK2 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2C3 | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- OR2T12 | c.418del p.L140* | Frame Shift Del (DEL) | VAF 39/224 reads (17%) | called by mutect2, pindel, varscan2
- OR2T2 | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 44/744 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- OR56B1 | c.71dup p.F26Ifs*64 | Frame Shift Ins (INS) | VAF 63/513 reads (12%) | called by mutect2, pindel, varscan2
- OR5D18 | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- OR6C65 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 91/427 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- OR7A17 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ORC2 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OSBPL6 | c.2738A>C p.N913T | Missense Mutation (SNP) | VAF 57/445 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OVOL1 | c.638A>C p.Y213S | Missense Mutation (SNP) | VAF 23/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PADI6 | c.1438C>G p.H480D | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1292G>A p.W431* (on ENST00000259318 / NM_001136562.3; = p.W662* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 28/207 reads (14%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1373A>G p.E458G | Missense Mutation (SNP) | VAF 62/612 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PCDHA8 | c.1314del p.A439Pfs*10 | Frame Shift Del (DEL) | VAF 128/442 reads (29%) | called by mutect2, varscan2
- PCDHB14 | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 181/657 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCYOX1L | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHACTR2 | c.1282A>G p.S428G | Missense Mutation (SNP) | VAF 72/509 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PHKA2 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PKHD1 | c.6710G>C p.R2237T | Missense Mutation (SNP) | VAF 76/582 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- PLA2G4A | c.1157dup p.L386Ffs*47 | Frame Shift Ins (INS) | VAF 67/353 reads (19%) | called by pindel, varscan2
- PLCB4 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHG4B | c.1697G>T p.G566V (on ENST00000283426; = p.G922V on NM_052909.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLXNC1 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PMFBP1 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- POU3F4 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 75/182 reads (41%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.1280G>T p.W427L | Missense Mutation (SNP) | VAF 103/752 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRKDC | c.9251A>C p.Q3084P | Missense Mutation (SNP) | VAF 40/393 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRKG1 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 109/502 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRLR | c.774G>C p.L258F | Missense Mutation (SNP) | VAF 15/433 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2
- PROKR1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PRTG | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- PSG8 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 130/405 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSKH2 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PTPN13 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 35/720 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRM | c.3014G>T p.R1005M | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRT | c.2425A>T p.T809S | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRZ1 | c.5822G>T p.G1941V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYROXD2 | c.507G>T p.L169F | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- RARB | c.643G>A p.D215N (on ENST00000383772 / NM_001290216.2; = p.D208N on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by mutect2, varscan2
- REELD1 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- REV3L | c.6027G>T p.W2009C | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIN2 | c.922G>A p.E308K (on ENST00000255006 / NM_001242581.1; = p.E259K on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/576 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- RIN2 | c.1053G>C p.E351D (on ENST00000255006 / NM_001242581.1; = p.E302D on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- RMDN2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 14/237 reads (6%) | called by muse, mutect2
- ROBO2 | c.3416C>A p.S1139Y | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RTL1 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RTL9 | c.778A>G p.M260V | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RYR1 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.11994G>T p.Q3998H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- S1PR5 | c.1010A>T p.Q337L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SALL1 | c.1345C>A p.H449N | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SBF2 | c.3650C>A p.A1217D | Missense Mutation (SNP) | VAF 48/462 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SCN2A | c.3818C>T p.A1273V | Missense Mutation (SNP) | VAF 77/579 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDCCAG8 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 20/601 reads (3%) | called by muse, mutect2
- SEMA5A | c.2757G>T p.Q919H | Missense Mutation (SNP) | VAF 172/486 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, varscan2
- SEMA6D | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEMA6D | c.1357G>C p.A453P | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SETBP1 | c.2305G>C p.V769L | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SFXN3 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 102/405 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SI | c.3119A>T p.K1040M | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2
- SIM1 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by mutect2, varscan2
- SIX3 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SKAP2 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLA2 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, varscan2
- SLC12A6 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A5 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLC17A9 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.02); called by muse, mutect2
- SLC18A2 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- SLC41A2 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC44A1 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 16/389 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- SLC4A8 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A4 | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLCO1A2 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLIT1 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG6 | c.855G>T p.R285S | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SNRNP27 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SORCS3 | c.2860A>T p.S954C | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SPEF2 | c.2764C>A p.P922T | Missense Mutation (SNP) | VAF 87/756 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPEF2 | c.4799T>A p.L1600H | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- SPEF2 | c.5206G>T p.D1736Y | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SRRM4 | c.1661G>T p.S554I | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, varscan2
- STARD6 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYN2 | c.981-2A>T p.X327_splice | Splice Site (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- SYNE1 | c.12986A>T p.E4329V (on ENST00000367255 / NM_182961.4; = p.E4258V on NM_033071.3) | Missense Mutation (SNP) | VAF 154/831 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- SYNE1 | c.5665_5667del p.Q1889del (on ENST00000367255 / NM_182961.4; = p.Q1896del on NM_033071.3) | In Frame Del (DEL) | VAF 56/441 reads (13%) | called by mutect2, pindel, varscan2
- SYNRG | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 36/504 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYP | c.200T>A p.I67N | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TARBP1 | c.3361G>T p.V1121F | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TBRG1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TEAD1 | c.322A>C p.K108Q | Missense Mutation (SNP) | VAF 22/697 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.431); called by muse, mutect2
- TENM3 | c.7441G>T p.G2481C | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TENM3 | c.7913A>G p.Q2638R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); called by muse, mutect2
- TEX13C | c.2410G>T p.G804W | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); called by muse, varscan2
- TF | c.1952G>T p.R651I | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TG | c.4540T>A p.C1514S | Missense Mutation (SNP) | VAF 74/821 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- TLN2 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR4 | c.966G>T p.R322S (on ENST00000355622 / NM_138554.5; = p.R282S on NM_003266.4) | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR7 | c.2382T>G p.F794L | Missense Mutation (SNP) | VAF 23/373 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2
- TMC3 | c.1070G>T p.W357L | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TMEM132A | c.1474G>T p.A492S (on ENST00000453848 / NM_178031.3; = p.A493S on NM_017870.4) | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TMEM132E | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TMEM132E | c.139T>A p.Y47N | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TMEM170A | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM176B | c.207G>T p.V69= | Splice Region (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- TMEM201 | c.1028A>T p.H343L | Missense Mutation (SNP) | VAF 98/426 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM252 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 54/465 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TMEM8B | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TMPRSS12 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2
- TMTC4 | c.844G>C p.G282R (on ENST00000376234 / NM_001350577.2; = p.G301R on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- TNRC6A | c.899G>C p.S300T | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOGARAM1 | c.3193G>C p.A1065P | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TRADD | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAPPC10 | c.1963A>T p.I655F | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.068); called by muse, mutect2
- TRAV8-6 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- TRGV1 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 92/488 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- TRIM32 | c.1395C>A p.H465Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.888); called by muse, mutect2
- TRIM49B | c.664A>T p.R222W | Missense Mutation (SNP) | VAF 174/581 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM49B | c.872T>A p.L291Q | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- TRPC5 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM2 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- TSPAN13 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 124/722 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TTN | c.16837A>T p.S5613C (on ENST00000591111; = p.S4686C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- UBXN7 | c.1264G>T p.G422* | Nonsense Mutation (SNP) | VAF 85/445 reads (19%) | called by muse, mutect2, varscan2
- UCHL5 | c.566-1G>T p.X189_splice | Splice Site (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- UHRF1 | c.1103G>A p.S368N (on ENST00000612630 / NM_001290050.1; = p.S381N on NM_013282.4) | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- UNC79 | c.827T>A p.M276K (on ENST00000393151 / NM_001346218.2; = p.M99K on NM_020818.5) | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- UNC80 | c.3299G>T p.G1100V | Missense Mutation (SNP) | VAF 53/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- USH1C | c.872C>A p.A291E | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- USH2A | c.10407C>A p.Y3469* | Nonsense Mutation (SNP) | VAF 55/272 reads (20%) | called by muse, mutect2, varscan2
- USP25 | c.882del p.M295Wfs*2 | Frame Shift Del (DEL) | VAF 54/480 reads (11%) | called by mutect2, pindel, varscan2
- VAMP7 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); called by muse, mutect2
- VDAC1 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2
- VNN3 | c.214-1G>T p.X72_splice | Splice Site (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- WDR41 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- WDR7 | c.4421G>T p.R1474L | Missense Mutation (SNP) | VAF 68/412 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDR97 | c.258A>T p.R86S | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WNK1 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 134/1120 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- WNK1 | c.2548C>T p.H850Y | Missense Mutation (SNP) | VAF 76/927 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.069); called by muse, mutect2
- ZBTB43 | c.66A>T p.K22N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.028); called by muse, mutect2
- ZBTB5 | c.1875G>C p.L625F | Missense Mutation (SNP) | VAF 59/770 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ZCWPW2 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- ZFHX2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZFHX4 | c.3279C>A p.N1093K | Missense Mutation (SNP) | VAF 153/599 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFPM2 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 87/503 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF134 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF165 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- ZNF184 | c.188A>T p.H63L | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF318 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- ZNF331 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF385D | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 79/543 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF518B | c.2692A>G p.R898G | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF573 | c.1844G>T p.C615F (on ENST00000536220 / NM_001172692.1; = p.C557F on NM_152360.3) | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF606 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZNF716 | c.224A>T p.Q75L | Missense Mutation (SNP) | VAF 130/603 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ZNF736 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ZNF75A | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ZNF831 | c.2823C>A p.Y941* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- ZZZ3 | c.1800A>T p.L600F | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ABCA13 | c.3306G>T p.S1102= | Silent (SNP) | VAF 26/373 reads (7%) | catalogued as rs745683720; called by muse, mutect2
- ABCA4 | c.1812C>T p.I604= | Silent (SNP) | VAF 67/686 reads (10%) | called by muse, mutect2
- ABCC11 | c.1518G>T p.G506= | Silent (SNP) | VAF 46/482 reads (10%) | catalogued as rs761077695, COSV62326725; called by muse, mutect2
- ABCC3 | c.2070C>T p.S690= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs778275597, COSV53324484; called by muse, mutect2, varscan2
- ADAMTS5 | c.1593C>T p.T531= | Silent (SNP) | VAF 97/599 reads (16%) | catalogued as COSV53176566; called by muse, mutect2, varscan2
- ADCY5 | c.603G>A p.A201= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV71901474; called by muse, mutect2, varscan2
- ADGRL3 | c.1869C>G p.V623= (on ENST00000506720 / NM_001322402.2; = p.V555= on NM_015236.6) | Silent (SNP) | VAF 32/296 reads (11%) | called by muse, mutect2, varscan2
- ADORA2A | c.924G>T p.L308= | Silent (SNP) | VAF 27/279 reads (10%) | called by muse, mutect2, varscan2
- AFF2 | c.3018C>A p.V1006= | Silent (SNP) | VAF 84/365 reads (23%) | called by muse, mutect2, varscan2
- AGO1 | c.705G>A p.V235= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1184303864; called by muse, mutect2, varscan2
- AL592490.1 | c.357C>T p.F119= | Silent (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- AMH | c.90A>G p.P30= | Silent (SNP) | VAF 46/203 reads (23%) | called by muse, mutect2, varscan2
- APBA2 | c.354G>T p.G118= | Silent (SNP) | VAF 42/326 reads (13%) | called by muse, mutect2, varscan2
- AQP3 | c.99C>T p.L33= | Silent (SNP) | VAF 22/288 reads (8%) | catalogued as rs1202263161; called by muse, mutect2
- ARHGAP45 | c.1278G>A p.A426= | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as rs560607854; called by muse, mutect2, varscan2
- ARHGEF18 | c.2661C>T p.A887= (on ENST00000359920 / NM_001130955.2; = p.A783= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.702T>A p.A234= | Silent (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- ASXL3 | c.2268C>A p.S756= | Silent (SNP) | VAF 42/261 reads (16%) | called by muse, mutect2, varscan2
- ATP8B3 | c.3201G>T p.V1067= | Silent (SNP) | VAF 22/164 reads (13%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3624C>A p.V1208= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as COSV58087750; called by muse, mutect2
- B4GALNT2 | c.1002C>T p.H334= | Silent (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- BACH2 | c.1914G>A p.K638= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- BCL11B | c.2265G>T p.P755= (on ENST00000357195 / NM_001282237.2; = p.P684= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/283 reads (14%) | called by muse, mutect2, varscan2
- BPTF | c.1200G>T p.G400= | Silent (SNP) | VAF 48/349 reads (14%) | called by muse, mutect2, varscan2
- C12orf71 | c.789T>A p.L263= | Silent (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- C16orf78 | c.534C>T p.S178= | Silent (SNP) | VAF 82/405 reads (20%) | catalogued as rs1275296604; called by muse, mutect2, varscan2
- C4orf54 | c.2409C>A p.P803= | Silent (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- CACNA1B | c.837C>T p.G279= | Silent (SNP) | VAF 23/298 reads (8%) | catalogued as rs199980453, COSV53131565; called by muse, mutect2
- CCT6B | c.1257T>G p.A419= | Silent (SNP) | VAF 17/281 reads (6%) | called by muse, mutect2
- CDH18 | c.1422G>T p.V474= | Silent (SNP) | VAF 34/457 reads (7%) | called by muse, mutect2
- CFAP61 | c.105C>T p.T35= | Silent (SNP) | VAF 37/282 reads (13%) | called by muse, mutect2, varscan2
- CLASP2 | c.2985C>T p.F995= (on ENST00000359576; = p.F994= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 64/242 reads (26%) | catalogued as rs747567627; called by muse, mutect2, varscan2
- CLIP2 | c.2871G>T p.L957= | Silent (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- CLUL1 | c.1191C>A p.I397= | Silent (SNP) | VAF 38/408 reads (9%) | catalogued as rs750562035; called by muse, mutect2
- COL13A1 | c.60G>A p.L20= | Silent (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- COL17A1 | c.1491G>A p.A497= | Silent (SNP) | VAF 81/662 reads (12%) | catalogued as rs143263539, CX167190; called by muse, mutect2, varscan2
- COL2A1 | c.519T>C p.P173= | Silent (SNP) | VAF 80/273 reads (29%) | called by muse, mutect2, varscan2
- CPXM2 | c.1653G>T p.L551= | Silent (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2
- CRYBG2 | c.3789C>A p.A1263= | Silent (SNP) | VAF 38/164 reads (23%) | called by muse, mutect2, varscan2
- CSF2RA | c.706C>A p.R236= | Silent (SNP) | VAF 96/386 reads (25%) | catalogued as COSV100817689; called by muse, mutect2, varscan2
- CSMD1 | c.8796G>C p.R2932= (on ENST00000520002; = p.R2931= on NM_033225.6) | Silent (SNP) | VAF 50/277 reads (18%) | called by muse, mutect2, varscan2
- CT47B1 | c.138G>T p.V46= | Silent (SNP) | VAF 44/275 reads (16%) | called by muse, mutect2, varscan2
- CTSC | c.135C>T p.S45= | Silent (SNP) | VAF 18/490 reads (4%) | called by muse, mutect2
- CTTNBP2 | c.2772T>A p.G924= | Silent (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- CYP2C18 | c.1239G>T p.L413= | Silent (SNP) | VAF 34/428 reads (8%) | called by muse, mutect2
- DCC | c.267G>A p.K89= | Silent (SNP) | VAF 77/562 reads (14%) | called by muse, mutect2, varscan2
- DDX31 | c.174C>A p.L58= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs774562359; called by muse, mutect2, varscan2
- DDX39A | c.69A>G p.Q23= | Silent (SNP) | VAF 73/324 reads (23%) | called by muse, mutect2, varscan2
- DENND1A | c.2097C>T p.I699= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, varscan2
- DMBX1 | c.1015C>T p.L339= | Silent (SNP) | VAF 67/338 reads (20%) | catalogued as rs1442997719; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1713G>T p.R571= | Silent (SNP) | VAF 116/331 reads (35%) | called by muse, mutect2, varscan2
- EFCAB6 | c.612C>T p.F204= | Silent (SNP) | VAF 28/317 reads (9%) | called by muse, mutect2
- EFEMP1 | c.486C>T p.G162= | Silent (SNP) | VAF 18/550 reads (3%) | called by muse, mutect2
- EMILIN1 | c.66C>A p.A22= | Silent (SNP) | VAF 57/254 reads (22%) | called by muse, mutect2, varscan2
- EVC | c.393C>T p.A131= | Silent (SNP) | VAF 65/558 reads (12%) | catalogued as rs374197757, COSV53829646; called by muse, mutect2, varscan2
- FAM131B | c.249C>A p.A83= | Silent (SNP) | VAF 72/445 reads (16%) | called by muse, mutect2, varscan2
- FAM181B | c.87C>T p.F29= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV61300592; called by muse, mutect2, varscan2
- FAT4 | c.11010G>A p.L3670= | Silent (SNP) | VAF 36/348 reads (10%) | catalogued as rs1467980403; called by muse, mutect2, varscan2
- FGF13 | c.663G>T p.G221= | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as COSV100263738; called by muse, mutect2
- FLG2 | c.6426G>A p.G2142= | Silent (SNP) | VAF 44/336 reads (13%) | catalogued as COSV66166883, COSV66172232; called by muse, mutect2, varscan2
- FLNC | c.2694C>A p.G898= | Silent (SNP) | VAF 49/339 reads (14%) | called by muse, mutect2, varscan2
- FLRT2 | c.1617C>T p.S539= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs985730494; called by mutect2, varscan2
- GNAS | c.78C>A p.P26= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs771863353; called by muse, mutect2, varscan2
- GRAMD2B | c.1176A>T p.P392= | Silent (SNP) | VAF 97/322 reads (30%) | catalogued as rs1238570748; called by muse, mutect2, varscan2
- GRIN2A | c.3081C>A p.S1027= | Silent (SNP) | VAF 34/249 reads (14%) | called by muse, mutect2, varscan2
- HTR1B | c.774C>A p.T258= | Silent (SNP) | VAF 11/242 reads (5%) | catalogued as COSV64051166; called by muse, mutect2
- IGF2BP2 | c.354A>T p.T118= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- IGLV1-47 | c.144C>A p.I48= | Silent (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- IL21 | c.51C>T p.V17= | Silent (SNP) | VAF 16/497 reads (3%) | catalogued as COSV52645350; called by muse, mutect2
- INPP5B | c.1821C>T p.L607= (on ENST00000373023; = p.L527= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/348 reads (5%) | called by muse, mutect2
- IRX1 | c.630C>T p.T210= | Silent (SNP) | VAF 147/333 reads (44%) | catalogued as rs764735861, COSV57362260; called by muse, mutect2, varscan2
- ITIH2 | c.1965G>T p.L655= | Silent (SNP) | VAF 46/492 reads (9%) | called by muse, mutect2
- JCHAIN | c.114C>A p.A38= | Silent (SNP) | VAF 18/436 reads (4%) | catalogued as COSV54659369; called by muse, mutect2
- JPH2 | c.798G>T p.L266= | Silent (SNP) | VAF 128/380 reads (34%) | called by muse, varscan2
- JUP | c.162G>T p.T54= | Silent (SNP) | VAF 85/322 reads (26%) | called by muse, mutect2, varscan2
- KCNH6 | c.1227G>A p.A409= | Silent (SNP) | VAF 23/230 reads (10%) | catalogued as rs764333218, COSV59006744; called by muse, mutect2
- KCNK15 | c.495G>T p.L165= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- KCNU1 | c.2784A>C p.T928= | Silent (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- KCNV2 | c.390C>G p.T130= | Silent (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- KIAA0100 | c.360G>A p.L120= | Silent (SNP) | VAF 28/322 reads (9%) | catalogued as rs377145439; called by muse, mutect2
- KIDINS220 | c.4686G>A p.P1562= | Silent (SNP) | VAF 31/235 reads (13%) | catalogued as rs777163980; called by muse, mutect2, varscan2
- KLHL34 | c.1308C>T p.G436= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- KMT2C | c.7191G>A p.Q2397= | Silent (SNP) | VAF 18/674 reads (3%) | catalogued as rs1420303634, COSV51390166; called by muse, mutect2
- KMT2D | c.15624G>C p.V5208= | Silent (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- LAMB4 | c.1803T>C p.V601= | Silent (SNP) | VAF 56/450 reads (12%) | called by muse, varscan2
- LARP4 | c.1842C>G p.P614= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- LILRA2 | c.756A>G p.R252= | Silent (SNP) | VAF 18/295 reads (6%) | catalogued as rs1380222240, COSV52190754; called by muse, mutect2
- LIPF | c.621A>T p.T207= | Silent (SNP) | VAF 18/311 reads (6%) | catalogued as COSV53286353; called by muse, mutect2
- LOXHD1 | c.1759C>A p.R587= | Silent (SNP) | VAF 34/311 reads (11%) | catalogued as CM121921; called by muse, mutect2, varscan2
- LPO | c.105C>A p.S35= | Silent (SNP) | VAF 59/373 reads (16%) | called by muse, mutect2, varscan2
- LRFN5 | c.570C>G p.T190= | Silent (SNP) | VAF 28/229 reads (12%) | catalogued as COSV53274732; called by muse, mutect2, varscan2
- LRRN3 | c.2088A>C p.V696= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- LUZP4 | c.810G>A p.Q270= | Silent (SNP) | VAF 77/453 reads (17%) | called by muse, mutect2, varscan2
- MAGEB16 | c.558G>T p.L186= | Silent (SNP) | VAF 90/227 reads (40%) | called by muse, mutect2
- MAGEB5 | c.822C>T p.P274= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2
- MARCHF11 | c.1089C>A p.T363= | Silent (SNP) | VAF 82/1230 reads (7%) | called by muse, mutect2
- MINDY4 | c.444A>T p.V148= | Silent (SNP) | VAF 104/442 reads (24%) | called by muse, mutect2, varscan2
- MMP16 | c.1779C>A p.P593= | Silent (SNP) | VAF 25/250 reads (10%) | catalogued as rs779096285, COSV54153214; called by muse, mutect2
- MSLN | c.825C>T p.S275= | Silent (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- MTSS1 | c.2217G>C p.V739= | Silent (SNP) | VAF 17/188 reads (9%) | catalogued as COSV52675284; called by muse, mutect2
- MUC16 | c.30321G>C p.V10107= | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.7869C>T p.S2623= | Silent (SNP) | VAF 30/219 reads (14%) | called by muse, mutect2, varscan2
- MUC19 | c.663C>T p.A221= | Silent (SNP) | VAF 32/424 reads (8%) | catalogued as rs1292955650; called by muse, mutect2
- MUC5B | c.9618C>A p.I3206= | Silent (SNP) | VAF 84/251 reads (33%) | catalogued as COSV71590419; called by muse, mutect2, varscan2
- MYO3B | c.2637T>A p.P879= | Silent (SNP) | VAF 44/336 reads (13%) | called by muse, mutect2, varscan2
- NCKAP1L | c.1804C>T p.L602= | Silent (SNP) | VAF 36/330 reads (11%) | called by muse, mutect2, varscan2
- NCKAP1L | c.2079A>G p.V693= | Silent (SNP) | VAF 74/281 reads (26%) | called by muse, mutect2, varscan2
- NEU4 | c.54G>T p.T18= (on ENST00000391969 / NM_001167602.3; = p.T30= on NM_080741.4) | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs371887569; called by muse, mutect2, varscan2
- NGF | c.282C>A p.P94= | Silent (SNP) | VAF 56/282 reads (20%) | catalogued as COSV65688973; called by muse, mutect2, varscan2
- NLGN4X | c.198C>A p.I66= | Silent (SNP) | VAF 74/384 reads (19%) | called by muse, mutect2, varscan2
- NPY2R | c.138G>T p.L46= | Silent (SNP) | VAF 16/380 reads (4%) | catalogued as COSV61527610; called by muse, mutect2
- NWD1 | c.4035T>A p.T1345= | Silent (SNP) | VAF 47/273 reads (17%) | called by muse, mutect2, varscan2
- NWD1 | c.4671C>T p.C1557= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as rs1378054578; called by muse, mutect2, varscan2
- OPCML | c.1008C>A p.T336= | Silent (SNP) | VAF 121/390 reads (31%) | catalogued as rs759709063; called by muse, mutect2, varscan2
- OR2C3 | c.297G>T p.V99= | Silent (SNP) | VAF 133/555 reads (24%) | called by muse, mutect2, varscan2
- OR2W3 | c.150G>A p.R50= | Silent (SNP) | VAF 37/305 reads (12%) | called by muse, mutect2, varscan2
- OR4B1 | c.813A>T p.V271= | Silent (SNP) | VAF 54/393 reads (14%) | called by muse, mutect2, varscan2
- OR4C15 | c.1002G>A p.L334= (on ENST00000314644; = p.L280= on NM_001001920.2) | Silent (SNP) | VAF 35/350 reads (10%) | catalogued as rs769561427, COSV100115651, COSV58953273; called by muse, mutect2, varscan2
- OR56A1 | c.360C>T p.V120= | Silent (SNP) | VAF 65/397 reads (16%) | called by muse, mutect2, varscan2
- OR5M11 | c.510C>A p.S170= | Silent (SNP) | VAF 23/222 reads (10%) | catalogued as COSV73142015; called by muse, mutect2, varscan2
- OR6K6 | c.822G>C p.V274= (on ENST00000368144; = p.V250= on NM_001005184.1) | Silent (SNP) | VAF 31/216 reads (14%) | called by muse, mutect2, varscan2
- PAPPA | c.4389C>A p.T1463= | Silent (SNP) | VAF 28/247 reads (11%) | catalogued as COSV60288952; called by muse, mutect2, varscan2
- PAPPA2 | c.4317C>A p.P1439= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as COSV62809604; called by muse, mutect2
- PARG | c.2424G>T p.G808= | Silent (SNP) | VAF 27/366 reads (7%) | called by muse, mutect2
- PCDH1 | c.1761G>T p.R587= | Silent (SNP) | VAF 30/162 reads (19%) | catalogued as rs113451110, COSV54613563; called by muse, mutect2, varscan2
- PCDH10 | c.1002C>A p.G334= | Silent (SNP) | VAF 50/450 reads (11%) | catalogued as COSV52104415; called by muse, mutect2, varscan2
- PCDHA12 | c.2016C>T p.N672= | Silent (SNP) | VAF 45/404 reads (11%) | catalogued as rs781785108, COSV56477226; called by muse, mutect2, varscan2
- PDZD2 | c.2877G>A p.Q959= | Silent (SNP) | VAF 17/604 reads (3%) | called by muse, mutect2
- PGS1 | c.114C>T p.L38= | Silent (SNP) | VAF 10/169 reads (6%) | catalogued as rs1230583405; called by muse, mutect2
- PIGO | c.1737A>T p.S579= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- PLB1 | c.3294C>A p.A1098= | Silent (SNP) | VAF 79/444 reads (18%) | catalogued as rs201645442, COSV59819010; called by muse, mutect2, varscan2
- POLR3A | c.2004G>T p.L668= | Silent (SNP) | VAF 47/423 reads (11%) | catalogued as rs372455673; called by muse, mutect2, varscan2
- POMT1 | c.1830C>T p.Y610= | Silent (SNP) | VAF 164/594 reads (28%) | catalogued as rs773343894, COSV61224903; called by muse, mutect2, varscan2
- PRAMEF12 | c.432C>A p.P144= | Silent (SNP) | VAF 102/380 reads (27%) | called by muse, mutect2, varscan2
- PRUNE2 | c.8922G>T p.G2974= | Silent (SNP) | VAF 96/471 reads (20%) | called by muse, mutect2, varscan2
- PTH2R | c.183T>C p.G61= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- RBM26 | c.1305T>A p.P435= | Silent (SNP) | VAF 14/467 reads (3%) | called by muse, mutect2
- RFX3 | c.1302G>T p.G434= | Silent (SNP) | VAF 57/264 reads (22%) | called by muse, mutect2, varscan2
- RNASE3 | c.285C>A p.L95= | Silent (SNP) | VAF 85/744 reads (11%) | catalogued as rs753505935, COSV58959770; called by muse, mutect2, varscan2
- RND2 | c.370C>A p.R124= | Silent (SNP) | VAF 22/294 reads (7%) | catalogued as rs552149919; called by muse, mutect2
- ROBO1 | c.2799G>T p.A933= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- ROR2 | c.2700C>A p.A900= | Silent (SNP) | VAF 50/261 reads (19%) | called by muse, mutect2, varscan2
- RORA | c.123G>A p.P41= | Silent (SNP) | VAF 53/348 reads (15%) | catalogued as rs1194690266; called by muse, mutect2, varscan2
- RRM2 | c.357G>A p.L119= | Silent (SNP) | VAF 14/358 reads (4%) | catalogued as COSV58815934; called by muse, mutect2
- RYR1 | c.3681C>A p.I1227= | Silent (SNP) | VAF 126/427 reads (30%) | catalogued as COSV62095611; called by muse, mutect2, varscan2
- RYR1 | c.9948G>C p.L3316= | Silent (SNP) | VAF 82/267 reads (31%) | called by muse, mutect2, varscan2
- RYR3 | c.11739C>T p.D3913= (on ENST00000389232; = p.D3914= on NM_001036.6) | Silent (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- SATL1 | c.1422C>A p.I474= (on ENST00000395409; = p.I661= on NM_001367857.2) | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- SCAF11 | c.2893C>A p.R965= | Silent (SNP) | VAF 29/253 reads (11%) | catalogued as rs112858085, COSV65474709; called by muse, mutect2, varscan2
- SCN7A | c.4170C>T p.V1390= | Silent (SNP) | VAF 15/274 reads (5%) | called by muse, mutect2
- SEM1 | c.93C>A p.P31= | Silent (SNP) | VAF 272/963 reads (28%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.336A>G p.T112= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- SFRP2 | c.333C>T p.I111= | Silent (SNP) | VAF 38/387 reads (10%) | called by muse, mutect2
- SHANK2 | c.3474G>T p.V1158= | Silent (SNP) | VAF 81/379 reads (21%) | called by muse, mutect2, varscan2
- SHARPIN | c.126G>C p.R42= | Silent (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2, varscan2
138 further variants in this file (0 protein-altering or splice-affecting, 28 silent, 110 other) are not listed here.
